Somatic mutation profile of tumor specimen TCGA-DK-AA6U-01A (aliquot TCGA-DK-AA6U-01A-11D-A391-08) from TCGA case TCGA-DK-AA6U, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Age at diagnosis: 64.6 years (23,611 days).
Specimen TCGA-DK-AA6U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 655c6bfc-2a28-46ba-9227-55f87bc612e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-AA6U-10A (Blood Derived Normal), aliquot TCGA-DK-AA6U-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee879b04-4c60-4100-b762-ae5d249436ff

The open-access MAF lists 486 somatic variants for this specimen: 366 protein-altering or splice-affecting, 106 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 319, Silent 106, Nonsense Mutation 29, Intron 8, Frame Shift Del 7, Splice Site 4, RNA 4, Splice Region 3, 5'Flank 2, In Frame Del 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 32/46 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- A4GNT | c.994A>T p.T332S | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV52629185; called by muse, mutect2, varscan2
- ABCA8 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52204002; called by muse, mutect2, varscan2
- ABCE1 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56847557; called by muse, mutect2, varscan2
- ABHD13 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV65535064; called by muse, mutect2, varscan2
- AC006059.2 | c.1976C>G p.T659S | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV59607526; called by muse, mutect2, varscan2
- AC104452.1 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56470017; called by muse, mutect2, varscan2
- ACADS | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54369277; called by muse, mutect2, varscan2
- ACTRT1 | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 149/200 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV64419607; called by muse, mutect2, varscan2
- ACY3 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.56); PolyPhen benign (0.099); catalogued as rs1255553806, COSV54829109; called by muse, mutect2, varscan2
- ADAM12 | c.2435C>A p.P812H | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1410991058, COSV64131186; called by muse, mutect2, varscan2
- ADAMTS12 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 81/156 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61266047; called by muse, mutect2, varscan2
- ADAMTS12 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV61266054; called by muse, mutect2, varscan2
- ADAMTS13 | c.2998C>T p.R1000C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs782761491, COSV63022569; called by muse, mutect2
- ADAMTS3 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV104378756, COSV54394503; called by muse, mutect2, varscan2
- ADGRV1 | c.1581G>T p.K527N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as rs773127336, COSV67987835; called by muse, mutect2, varscan2
- AGAP2 | c.766G>T p.V256F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99223518; called by muse, mutect2
- AHR | c.1149G>T p.Q383H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54121404, COSV54127162; called by muse, mutect2
- AKAP3 | c.881C>G p.S294C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57417682; called by muse, mutect2, varscan2
- ALDH7A1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as COSV100778273; called by muse, mutect2
- ALG2 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99445575; called by muse, mutect2, varscan2
- ALLC | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as rs753814303, COSV52996477; called by muse, varscan2
- ALPL | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM050178, COSV66376342; called by muse, mutect2, varscan2
- ANKRD55 | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 116/285 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61947574; called by muse, mutect2, varscan2
- ANKS1A | c.3098A>G p.H1033R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64461666; called by muse, mutect2, varscan2
- AP3S2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60518767; called by muse, mutect2, varscan2
- APOF | c.627G>C p.K209N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as COSV58476023; called by muse, mutect2, varscan2
- AQP6 | c.263C>A p.A88D | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143331466, COSV59646491; called by muse, mutect2, varscan2
- ARHGAP39 | c.1595G>A p.S532N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1340415985, COSV99431578; called by muse, mutect2, varscan2
- ARIH1 | c.1604G>T p.R535L | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1276382860, COSV65911896; called by muse, mutect2, varscan2
- ARIH2 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100711351, COSV62705278; called by muse, mutect2
- ARMCX3 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | catalogued as COSV100362290; called by muse, mutect2, varscan2
- ASTE1 | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53909014; called by muse, mutect2, varscan2
- ATP6AP1 | c.404C>G p.A135G | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV62340859, COSV62341050; called by muse, mutect2, varscan2
- ATP8A1 | c.1606G>T p.G536W | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52538236, COSV52549801; called by muse, mutect2, varscan2
- ATXN7L2 | c.1991C>G p.S664C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs772939744, COSV60205175; called by muse, mutect2, varscan2
- AURKA | c.750G>C p.K250N | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57168855; called by muse, mutect2
- BCHE | c.681del p.G228Efs*34 | Frame Shift Del (DEL) | VAF 37/90 reads (41%) | catalogued as COSV52258089; called by mutect2, pindel, varscan2
- BCL6 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs369842677, COSV51652397; called by muse, mutect2
- BIRC6 | c.14464G>A p.D4822N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV70201073; called by muse, mutect2, varscan2
- BNC2 | c.1441A>T p.S481C | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66149842; called by muse, mutect2, varscan2
- BPIFC | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as COSV55913013; called by muse, mutect2, varscan2
- C15orf39 | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV62297069; called by muse, mutect2, varscan2
- C1orf127 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as rs1311508488, COSV100983493, COSV65439268; called by muse, mutect2, varscan2
- C1orf87 | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376379353; called by muse, mutect2, varscan2
- C22orf31 | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 33/160 reads (21%) | catalogued as rs1187090925, COSV99326400; called by muse, mutect2, varscan2
- C8A | c.1742C>A p.T581K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV63484861; called by muse, mutect2, varscan2
- CA5A | c.482C>A p.S161Y | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59240041; called by muse, mutect2
- CAAP1 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV100445186; called by muse, mutect2
- CABYR | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1241462088, COSV59111391; called by muse, mutect2, varscan2
- CACNA1A | c.5948G>C p.R1983P | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV64200989; called by muse, mutect2, varscan2
- CACNA2D3 | c.1889G>C p.R630P | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.346); catalogued as COSV55530510, COSV55549359; called by muse, mutect2, varscan2
- CAPN5 | c.1481C>T p.S494L (on ENST00000456580; = p.S454L on NM_004055.5) | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV53688902; called by muse, mutect2
- CARD11 | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.175); catalogued as COSV67800015; called by muse, mutect2
- CARD18 | c.254C>G p.S85* | Nonsense Mutation (SNP) | VAF 17/173 reads (10%) | catalogued as COSV101596036; called by muse, mutect2, varscan2
- CASP3 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57725273; called by muse, mutect2, varscan2
- CBFA2T2 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60074435; called by muse, mutect2
- CBLB | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99913633; called by muse, mutect2
- CCDC115 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.458); catalogued as COSV52092100; called by muse, mutect2
- CCDC198 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as COSV53602468; called by muse, mutect2, varscan2
- CCNI | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52960129; called by muse, mutect2, varscan2
- CD207 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.367); catalogued as rs1553400958, COSV69652271; called by muse, mutect2, varscan2
- CEACAM21 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV51814627; called by muse, mutect2, varscan2
- CELSR3 | c.3047C>T p.S1016F | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50887188; called by muse, mutect2, varscan2
- CEP97 | c.890A>T p.Q297L | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV59125288; called by muse, mutect2, varscan2
- CES3 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57594041, COSV57594599; called by muse, mutect2, varscan2
- CHGB | c.588C>A p.N196K | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV66760391, COSV66760799; called by muse, mutect2, varscan2
- CLMN | c.1539G>C p.E513D | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV54183470; called by muse, mutect2, varscan2
- CNTNAP1 | c.2945C>T p.T982M | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as rs757116427, COSV52851437; called by muse, mutect2
- COG8 | c.523C>G p.L175V | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54742655; called by muse, mutect2, varscan2
- COL16A1 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV54708253; called by muse, mutect2, varscan2
- COL24A1 | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV65308203; called by muse, mutect2, varscan2
- COL4A4 | c.4880G>A p.R1627K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100307031, COSV61633330; called by muse, mutect2, varscan2
- COPA | c.2567-1G>C p.X856_splice | Splice Site (SNP) | VAF 42/137 reads (31%) | catalogued as COSV54104199; called by muse, mutect2, varscan2
- CPNE3 | c.581T>C p.F194S | Missense Mutation (SNP) | VAF 19/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52207327; called by muse, mutect2
- CRB1 | c.1641G>T p.Q547H | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.87); catalogued as COSV66331135; called by muse, mutect2, varscan2
- CREBBP | c.2731C>T p.Q911* | Nonsense Mutation (SNP) | VAF 34/73 reads (47%) | catalogued as COSV52116787; called by muse, mutect2, varscan2
- CROCC | c.5719G>T p.D1907Y | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65003859; called by muse, mutect2, varscan2
- CSMD2 | c.10304G>A p.R3435K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV53923276; called by muse, mutect2, varscan2
- CSN3 | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.26); catalogued as COSV59244348; called by muse, mutect2, varscan2
- CST7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/78 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV65195871; called by muse, mutect2, varscan2
- CYB561A3 | c.283G>T p.V95F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53652388; called by muse, mutect2, varscan2
- DDX3X | c.1792G>T p.A598S (on ENST00000399959; = p.A599S on NM_001356.5) | Missense Mutation (SNP) | VAF 48/62 reads (77%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.508); catalogued as COSV67863869; called by muse, mutect2, varscan2
- DEUP1 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99977267; called by muse, mutect2
- DHX57 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV54886629; called by muse, mutect2, varscan2
- DMTN | c.1066A>G p.T356A | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as COSV56113024; called by muse, mutect2, varscan2
- DNAH1 | c.12382C>G p.L4128V | Missense Mutation (SNP) | VAF 142/468 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as COSV56234859; called by muse, varscan2
- DNAH11 | c.8597G>C p.R2866T | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV60961494; called by muse, mutect2, varscan2
- DNAH3 | c.6445G>C p.E2149Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54529093; called by muse, mutect2, varscan2
- DNAH7 | c.6310C>G p.P2104A | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); catalogued as COSV56769913; called by muse, mutect2
- DNAH8 | c.8417C>A p.S2806* | Nonsense Mutation (SNP) | VAF 21/177 reads (12%) | catalogued as COSV100545871; called by muse, mutect2, varscan2
- DNAJB6 | c.620+1G>T p.X207_splice | Splice Site (SNP) | VAF 27/87 reads (31%) | catalogued as COSV51096632; called by muse, mutect2, varscan2
- DNMT1 | c.2916C>G p.H972Q | Missense Mutation (SNP) | VAF 109/228 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.449); catalogued as COSV61580327; called by muse, mutect2, varscan2
- DSG3 | c.375C>T p.I125= | Splice Region (SNP) | VAF 8/70 reads (11%) | catalogued as COSV57126718, COSV57127169; called by muse, mutect2, varscan2
- DST | c.20590G>T p.E6864* (on ENST00000361203 / NM_001374722.1; = p.E4561* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 43/129 reads (33%) | catalogued as COSV99757397; called by muse, mutect2, varscan2
- EBF1 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs761796846, COSV58182834; called by muse, mutect2, varscan2
- EHMT2 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.29); catalogued as COSV64996457; called by muse, mutect2, varscan2
- EIF2S2 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs767028331, COSV66621770; called by muse, mutect2, varscan2
- ELFN2 | c.449G>T p.C150F | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV68744746, COSV68745036; called by muse, mutect2, varscan2
- ELL3 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157744617, COSV55856892; called by muse, mutect2
- ELOA2 | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV55301257; called by muse, mutect2, varscan2
- ENPP7 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100093484, COSV60386014; called by muse, mutect2, varscan2
- EP300 | c.584C>G p.S195* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as COSV54333511, COSV99608938; called by muse, mutect2, varscan2
- EP300 | c.3619G>C p.E1207Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV54335371, COSV54346086; called by muse, mutect2, varscan2
- EPHB1 | c.1370C>A p.P457Q | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV67653944, COSV67656557, COSV67663588; called by muse, mutect2, varscan2
- EPHB1 | c.2608C>T p.R870W | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs749666684, COSV67655830; called by muse, mutect2, varscan2
- ESYT3 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV67441222; called by muse, mutect2
- ETFB | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100164273, COSV58536345; called by muse, mutect2
- EXT1 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV65481085; called by muse, mutect2, varscan2
- EYS | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV60982329; called by muse, mutect2, varscan2
- F13B | c.687A>C p.Q229H | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs961932812, COSV66374386; called by muse, mutect2, varscan2
- FAM13C | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53250566; called by muse, mutect2, varscan2
- FANCA | c.4316G>C p.R1439T | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.297); catalogued as rs587778322, COSV57069534; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- FASTKD3 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV52942381; called by muse, mutect2, varscan2
- FBN1 | c.6361C>A p.P2121T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV57320199; called by muse, mutect2, varscan2
- FBXL13 | c.1012T>C p.S338P | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57539426; called by muse, mutect2
- FBXL7 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750262820, COSV61647807; called by muse, mutect2, varscan2
- FBXO22 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.17); catalogued as COSV57617818; called by muse, mutect2, varscan2
- FNDC8 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.656); catalogued as rs898252029, COSV50101834; called by muse, mutect2, varscan2
- FOLH1 | c.1814G>A p.R605K | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57050899, COSV99923355; called by muse, mutect2, varscan2
- FZD6 | c.734C>G p.S245C | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62471719; called by muse, mutect2, varscan2
- GAL3ST3 | c.268C>G p.H90D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV100360900; called by muse, varscan2
- GAREM1 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52511335; called by muse, mutect2, varscan2
- GBA3 | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV101545528; called by muse, mutect2, varscan2
- GCM2 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV65275880; called by muse, mutect2, varscan2
- GLIS1 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs369266481, COSV56550362; called by muse, mutect2, varscan2
- GLYCTK | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59794002; called by muse, mutect2, varscan2
- GLYR1 | c.297G>A p.T99= | Splice Region (SNP) | VAF 9/101 reads (9%) | catalogued as rs756278858, COSV58927530; called by muse, mutect2
- GNAT3 | c.778T>C p.S260P | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV101242398; called by muse, mutect2, varscan2
- GOLGB1 | c.9351G>C p.K3117N | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV61463852, COSV61466965; called by muse, mutect2
- GOLIM4 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 63/120 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV58330293; called by muse, mutect2, varscan2
- GOLM2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV55464224; called by muse, mutect2
- GORAB | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM146480, COSV63026294; called by muse, mutect2
- GRID1 | c.2820C>A p.S940R | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as COSV60034842; called by muse, mutect2, varscan2
- H2BC7 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.17); catalogued as rs762625852, COSV61912061; called by muse, mutect2, varscan2
- HDGFL2 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious, low confidence (0); catalogued as COSV100012281; called by muse, mutect2
- HFM1 | c.2756T>C p.F919S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54029810; called by muse, mutect2, varscan2
- HK1 | c.1616G>T p.R539L | Missense Mutation (SNP) | VAF 102/126 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53854684, COSV53860025; called by muse, mutect2, varscan2
- HMCN1 | c.1629C>G p.I543M | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV54909695; called by muse, mutect2, varscan2
- HNMT | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.7); catalogued as COSV54508463; called by muse, mutect2, varscan2
- HNRNPUL2 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 132/327 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53666051; called by muse, mutect2, varscan2
- HSPA13 | c.742A>T p.M248L | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV53465534; called by muse, mutect2, varscan2
- IGKV4-1 | c.123C>G p.I41M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as rs749373126; called by mutect2, varscan2
- ILDR2 | c.374T>A p.V125D | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV54832202; called by muse, mutect2, varscan2
- INKA1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs776374917, COSV60967853; called by muse, mutect2, varscan2
- INSR | c.1557C>A p.Y519* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100252549; called by muse, mutect2, varscan2
- INVS | c.2698C>A p.L900M | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.054); catalogued as COSV52443739; called by muse, mutect2, varscan2
- ISOC2 | c.511G>A p.D171N (on ENST00000425675 / NM_001136201.2; = p.D187N on NM_024710.3) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs1249424718, COSV50035096; called by muse, mutect2, varscan2
- ITGAM | c.1881C>G p.F627L (on ENST00000648685 / NM_001145808.2; = p.F626L on NM_000632.4) | Missense Mutation (SNP) | VAF 132/290 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54938391; called by muse, mutect2, varscan2
- ITGAX | c.1318T>C p.S440P | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV51647003; called by muse, mutect2, varscan2
- KANK4 | c.1466C>T p.S489F | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV62987378, COSV62989676; called by muse, mutect2, varscan2
- KCNN1 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV55839606; called by muse, mutect2, varscan2
- KCTD8 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1425210751, COSV63588836, COSV63590764; called by muse, mutect2, varscan2
- KIAA1755 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 78/234 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV54077521; called by muse, mutect2, varscan2
- KIR2DL4 | c.1018G>A p.A340T (on ENST00000396284; = p.A266T on NM_001080770.2) | Missense Mutation (SNP) | VAF 50/584 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.209); catalogued as rs763530813, COSV58495097; called by muse, mutect2
- KLHDC7A | c.1318A>T p.T440S | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.027); catalogued as COSV68770029, COSV68770101; called by muse, mutect2, varscan2
- KLK13 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 119/235 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); catalogued as COSV50067170; called by muse, mutect2, varscan2
- KMT2D | c.2782C>T p.Q928* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as COSV56458548; called by muse, mutect2, varscan2
- KMT2D | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99983052; called by muse, mutect2, varscan2
- KNG1 | c.415C>A p.Q139K | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV53978693; called by muse, mutect2, varscan2
- KNG1 | c.416A>G p.Q139R | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV53978711; called by muse, mutect2, varscan2
- KRTAP26-1 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 95/206 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs1041310441, COSV62128948; called by muse, mutect2, varscan2
- KRTAP9-8 | c.10T>G p.C4G | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54200175; called by muse, mutect2, varscan2
- LAMA1 | c.1798G>A p.V600I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as COSV67532944; called by muse, mutect2, varscan2
- LAMA5 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1307854974, COSV53362475, COSV53364977; called by muse, mutect2, varscan2
- LANCL2 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54650070; called by muse, mutect2
- LARP1B | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.3); catalogued as COSV52798896; called by muse, mutect2, varscan2
- LCE2D | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.023); catalogued as COSV64229065; called by muse, mutect2, varscan2
- LCORL | c.162G>C p.E54D | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV58836881; called by muse, mutect2, varscan2
- LGR4 | c.2717C>T p.S906F | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747119729, COSV58726197; called by muse, mutect2, varscan2
- LGR6 | c.2693C>T p.S898L (on ENST00000367278 / NM_001017403.1; = p.S846L on NM_021636.3) | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV55159318; called by muse, mutect2, varscan2
- LILRB4 | c.734C>A p.P245H | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1342318158, COSV54407133, COSV99553878; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.248G>T p.C83F | Missense Mutation (SNP) | VAF 62/101 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53280603; called by muse, mutect2, varscan2
- LRBA | c.4139C>T p.S1380L | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1353022856, COSV63949625; called by muse, mutect2, varscan2
- LRRC37B | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58952897; called by muse, mutect2
- LRRC4C | c.1915C>G p.Q639E | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV53428905; called by muse, mutect2, varscan2
- LRRTM1 | c.934G>C p.A312P | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV54443378, COSV54444809, COSV99702291; called by muse, mutect2, varscan2
- LYST | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV67706848, COSV67708358; called by muse, mutect2
- LZTS2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs773834150, COSV64651301; called by muse, mutect2, varscan2
- MAB21L3 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1055539851, COSV65674035; called by muse, mutect2, varscan2
- MBD1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV54002989, COSV54003048; called by muse, mutect2, varscan2
- MBD6 | c.745C>A p.H249N | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV63075183; called by muse, mutect2, varscan2
- MCM8 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as COSV52544132; called by muse, varscan2
- MCTP1 | c.2312A>T p.K771I | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56520785; called by muse, mutect2, varscan2
- MED12L | c.1870C>T p.R624* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99853586; called by muse, mutect2, varscan2
- MED28 | c.220C>G p.R74G | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52846202, COSV52846579; called by muse, mutect2
- MICAL2 | c.2092G>A p.G698S | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV56321629; called by muse, mutect2, varscan2
- MIOS | c.783G>C p.L261F | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV60769275; called by muse, mutect2, varscan2
- MMP16 | c.1721C>A p.A574D | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV54171100; called by muse, mutect2, varscan2
- MMRN1 | c.1782C>A p.D594E | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV53336225; called by muse, mutect2, varscan2
- MPEG1 | c.2024C>A p.A675D | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV57091860; called by muse, mutect2, varscan2
- MRPS18B | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs144633864; called by muse, mutect2, varscan2
- MSGN1 | c.84C>G p.D28E | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.247); catalogued as COSV55263064; called by muse, mutect2, varscan2
- MTMR4 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 16/161 reads (10%) | catalogued as rs748480906, COSV100051133; called by muse, mutect2, varscan2
- MUC16 | c.33086C>A p.S11029* | Nonsense Mutation (SNP) | VAF 58/103 reads (56%) | catalogued as COSV101200227, COSV67461137; called by muse, mutect2, varscan2
- MUC16 | c.30887G>C p.R10296P | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.676); catalogued as COSV67474078; called by muse, mutect2, varscan2
- MUC16 | c.20747C>A p.P6916Q | Missense Mutation (SNP) | VAF 92/199 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV67474086; called by muse, mutect2, varscan2
- MUC16 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV67474093; called by muse, mutect2, varscan2
- MUC17 | c.2210T>G p.M737R | Missense Mutation (SNP) | VAF 123/261 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV60292184; called by muse, mutect2, varscan2
- MVP | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV62422358; called by muse, mutect2
- MYH9 | c.320C>G p.S107* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV53391742; called by muse, mutect2, varscan2
- MYO1F | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV57792122; called by muse, mutect2, varscan2
- NAA10 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV64170048; called by muse, mutect2, varscan2
- NCOR2 | c.1252G>C p.D418H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62299516; called by muse, mutect2, varscan2
- NDST4 | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV52123973; called by muse, mutect2, varscan2
- NFXL1 | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV61198867; called by muse, mutect2, varscan2
- NID1 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs371242407; called by muse, mutect2, varscan2
- NIPBL | c.5917C>G p.Q1973E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs868722572, COSV56955239; called by muse, mutect2, varscan2
- NLRP7 | c.743T>C p.I248T | Missense Mutation (SNP) | VAF 103/208 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV60176343; called by muse, mutect2, varscan2
- NLRP8 | c.1453A>G p.T485A | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV52589248; called by muse, mutect2
- NLRP9 | c.1087A>T p.N363Y | Missense Mutation (SNP) | VAF 120/230 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV60464396; called by muse, mutect2, varscan2
- NOM1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV51980591; called by muse, mutect2, varscan2
- NPHP1 | c.882G>T p.R294S | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.018); catalogued as COSV57209465; called by muse, mutect2, varscan2
- NRXN1 | c.2710del p.A904Qfs*15 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | catalogued as COSV58462602; called by mutect2, pindel, varscan2
- NRXN2 | c.1519C>A p.P507T | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55455946; called by muse, mutect2, varscan2
- NUP188 | c.124del p.R42Dfs*3 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | catalogued as COSV65362555, COSV65362947; called by mutect2, pindel, varscan2
- NXPE3 | c.562G>T p.V188F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56290414; called by muse, mutect2, varscan2
- OGDH | c.1161G>C p.K387N | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56052088, COSV56058759; called by muse, mutect2, varscan2
- OR2V2 | c.239C>G p.P80R | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV60315861; called by muse, mutect2, varscan2
- OR5B3 | c.873G>C p.R291S | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs761564337, COSV58676756, COSV58677776; called by muse, mutect2, varscan2
- OR5M10 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV101595856, COSV73242351; called by muse, mutect2, varscan2
- OR5T1 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV100479143, COSV57303259; called by muse, mutect2, varscan2
- OR8H3 | c.492C>A p.S164R | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.151); catalogued as COSV57909620; called by muse, mutect2
- OR8I2 | c.923T>A p.L308H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100136130; called by muse, mutect2, varscan2
- OR9A2 | c.479T>G p.F160C | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.513); catalogued as COSV63306757; called by muse, mutect2, varscan2
- OVCH1 | c.2418G>A p.W806* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as rs766964651, COSV58960324; called by muse, mutect2, varscan2
- P4HTM | c.1148G>A p.R383K (on ENST00000383729 / NM_177939.3; = p.R444K on NM_177938.2) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as COSV59087656; called by muse, mutect2, varscan2
- PAPPA2 | c.3284C>A p.A1095D | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV62800705; called by muse, mutect2, varscan2
- PARP4 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.534); catalogued as rs1306406737, COSV67962619; called by muse, mutect2
- PAX1 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV68272211; called by muse, mutect2, varscan2
- PAX5 | c.841C>G p.L281V | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV63906280, COSV63913451; called by muse, mutect2
- PAXBP1 | c.2689C>T p.H897Y | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); catalogued as COSV59507644, COSV59507955; called by muse, mutect2
- PBX2 | c.122G>C p.S41T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV66709045; called by muse, mutect2, varscan2
- PCDH17 | c.719G>A p.S240N | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.029); catalogued as COSV64975376; called by muse, mutect2, varscan2
- PCDHB12 | c.847C>A p.H283N | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV53397748; called by muse, mutect2, varscan2
- PCDHB12 | c.1456G>T p.V486F | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV53397758; called by muse, mutect2, varscan2
- PCDHGA3 | c.2157G>T p.W719C | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV53968253; called by muse, mutect2, varscan2
- PCDHGB6 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as rs757628906, COSV53968275; called by muse, mutect2, varscan2
- PCDHGC4 | c.1669G>T p.D557Y | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52755234, COSV52774311; called by muse, mutect2, varscan2
- PCSK9 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs778562344, COSV56162829, COSV56164468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE4DIP | c.2642G>C p.R881T | Missense Mutation (SNP) | VAF 161/588 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57701580; called by muse, mutect2, varscan2
- PDZRN3 | c.1979C>A p.T660N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV55204259; called by muse, mutect2, varscan2
- PER2 | c.231-1G>A p.X77_splice | Splice Site (SNP) | VAF 816/866 reads (94%) | catalogued as COSV54524700; called by muse, mutect2, varscan2
- PGBD4 | c.1204G>C p.D402H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.356); catalogued as COSV56628181; called by muse, mutect2, varscan2
- PHOSPHO2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.215); catalogued as COSV55866960, COSV55867990, COSV99067975; called by muse, mutect2, varscan2
- PIK3R6 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.858); catalogued as COSV61003813; called by muse, mutect2, varscan2
- PITX2 | c.596C>T p.S199F (on ENST00000354925 / NM_001204397.1; = p.S206F on NM_000325.6) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60741321; called by muse, mutect2, varscan2
- PKHD1 | c.9961G>C p.D3321H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61881632, COSV61885464; called by muse, mutect2
- PLA2G4C | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.179); catalogued as COSV62786008; called by muse, mutect2, varscan2
- PLXNB1 | c.5516A>T p.Y1839F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56491013; called by muse, mutect2, varscan2
- PMFBP1 | c.2245G>A p.D749N (on ENST00000537465; = p.D744N on NM_031293.3) | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as rs1192835715, COSV52826099; called by muse, mutect2, varscan2
- POLR1C | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV54831226; called by mutect2, varscan2
- POU3F2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100098935; called by muse, mutect2
- PPP1R12A | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); catalogued as COSV54109812; called by muse, mutect2, varscan2
- PRKAG1 | c.931G>C p.G311R | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60293179; called by muse, mutect2, varscan2
- PROKR2 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as rs1471050027, COSV54087284; called by muse, mutect2, varscan2
- PTCD1 | c.904T>A p.Y302N | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV52864524, COSV52868025; called by muse, mutect2, varscan2
- PTH2R | c.1306G>T p.D436Y | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1453582463, COSV55917042; called by muse, mutect2, varscan2
- PTPRF | c.337C>A p.L113M | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as COSV63446011; called by muse, mutect2, varscan2
- PTTG1 | c.305G>A p.S102N | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1298074891, COSV51788477; called by muse, mutect2, varscan2
- PYGM | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs749507354, COSV51219382; called by muse, mutect2, varscan2
- QRICH1 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1321243889, COSV62616170; called by muse, mutect2
- RABGAP1 | c.2515G>C p.E839Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.067); catalogued as COSV65380343; called by muse, mutect2, varscan2
- RBL2 | c.814C>G p.P272A | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV50879979; called by muse, mutect2, varscan2
- RBM47 | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); catalogued as COSV55936973; called by muse, mutect2, varscan2
- RC3H2 | c.2708C>G p.S903* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100605713; called by muse, mutect2, varscan2
- RDH8 | c.424G>C p.V142L (on ENST00000651512; = p.V122L on NM_015725.4) | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.828); catalogued as COSV50674418, COSV50675592, COSV50678474; called by muse, mutect2, varscan2
- RELN | c.8888C>G p.T2963S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.101); catalogued as COSV59010154; called by muse, mutect2, varscan2
- RHBDL3 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); catalogued as rs1346143008, COSV52184651; called by muse, mutect2
- RHEB | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV100062098, COSV100062173; called by muse, mutect2
- RICTOR | c.5068G>A p.E1690K | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV57124042; called by muse, mutect2
- RNF208 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1264653028, COSV104417373; called by muse, mutect2
- RSPH14 | c.779T>A p.V260E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV53269524; called by muse, mutect2, varscan2
- RYR1 | c.4550G>T p.C1517F | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1321260327, COSV62100759; called by muse, mutect2, varscan2
- RYR2 | c.12423C>A p.S4141R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV63686018, COSV63700741; called by muse, mutect2, varscan2
- SCN11A | c.5062G>C p.A1688P | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV56565470, COSV56572282; called by muse, mutect2, varscan2
- SCN9A | c.37G>T p.V13F | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV57613534; called by muse, mutect2, varscan2
- SEC14L1 | c.288G>T p.E96D | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.539); catalogued as COSV66722930; called by muse, mutect2, varscan2
- SEC14L5 | c.836A>C p.D279A | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV52039271; called by muse, mutect2, varscan2
- SENP8 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV61768070; called by muse, mutect2, varscan2
- SFMBT1 | c.1538C>G p.S513* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV56257346, COSV99965715; called by muse, mutect2, varscan2
- SGK3 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1353384001, COSV61895132, COSV61896180; called by muse, mutect2, varscan2
- SHANK1 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs941454412, COSV53247657; called by muse, mutect2, varscan2
- SIGLEC11 | c.1678G>T p.G560C | Missense Mutation (SNP) | VAF 66/104 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.408); catalogued as COSV68567735; called by muse, mutect2, varscan2
- SLC41A2 | c.1663G>C p.A555P | Missense Mutation (SNP) | VAF 104/292 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51606621; called by muse, mutect2, varscan2
- SLC4A4 | c.1245G>A p.M415I (on ENST00000264485 / NM_001098484.3; = p.M371I on NM_003759.4) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.094); catalogued as COSV52622663; called by muse, mutect2, varscan2
- SLC5A3 | c.1024A>C p.S342R | Missense Mutation (SNP) | VAF 86/166 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62970580; called by muse, mutect2, varscan2
- SLC6A12 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV62885434; called by muse, mutect2, varscan2
- SLIT2 | c.2163C>G p.C721W | Missense Mutation (SNP) | VAF 94/274 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56577171; called by muse, mutect2, varscan2
- SMC2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); catalogued as rs760941119, COSV53959768; called by muse, mutect2, varscan2
- SPHKAP | c.4525C>A p.P1509T | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as rs776554607, COSV60883194; called by muse, mutect2, varscan2
- SRRM1 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); catalogued as COSV100104155, COSV60478219; called by muse, mutect2, varscan2
- SSBP1 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs767820643, COSV54680930; called by muse, mutect2, varscan2
- SSH2 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs368379165; called by muse, mutect2, varscan2
- STAB2 | c.5509G>T p.G1837C | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66341043; called by muse, mutect2, varscan2
- STEAP1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV51882023; called by muse, mutect2
- SYN3 | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60510326; called by muse, mutect2, varscan2
- SYNDIG1 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.043); catalogued as COSV65236108; called by muse, mutect2
- SYNPO2 | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV61107334, COSV61112769; called by muse, mutect2, varscan2
- SYTL2 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV60360077; called by muse, mutect2, varscan2
- TAOK1 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.15); catalogued as COSV55593545; called by muse, mutect2, varscan2
- TBATA | c.604C>A p.R202S | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV54719718; called by muse, mutect2, varscan2
- TBC1D8 | c.2837C>G p.S946* | Nonsense Mutation (SNP) | VAF 18/120 reads (15%) | catalogued as COSV99961514; called by muse, mutect2, varscan2
- TBCE | c.593C>G p.S198C (on ENST00000366601; = p.S261C on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV64006419; called by muse, mutect2
- TECTA | c.2794G>A p.V932I | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as rs200340759, COSV50725210; called by muse, mutect2, varscan2
- TEX9 | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV100771583, COSV61878879; called by muse, mutect2, varscan2
- TFG | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs777143620, COSV53749299, COSV53750174; called by muse, mutect2, varscan2
- TFPI2 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.266); catalogued as rs770380317, COSV55990401, COSV55992087; called by muse, mutect2
- TIGD4 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV58549948; called by muse, mutect2
- TMEM225 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs771821395, COSV66693556; called by muse, mutect2, varscan2
- TMEM95 | c.413G>T p.S138I (on ENST00000576060 / NM_001320436.2; = p.S146I on NM_198154.3) | Missense Mutation (SNP) | VAF 88/131 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV50136811; called by muse, mutect2, varscan2
- TNIK | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52685470; called by muse, mutect2, varscan2
- TNNI1 | c.309C>A p.D103E | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.942); catalogued as rs1389159109, COSV60189802; called by muse, mutect2, varscan2
- TNPO2 | c.1575T>A p.F525L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV63508710; called by muse, mutect2, varscan2
- TP53BP2 | c.1124C>T p.P375L (on ENST00000343537 / NM_001031685.3; = p.P246L on NM_005426.2) | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as rs767048169, COSV59069592; called by muse, mutect2, varscan2
- TRMT12 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60777306; called by muse, mutect2
- TRPA1 | c.2392A>T p.N798Y | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1479110903, COSV100084038, COSV51564617; called by muse, mutect2, varscan2
- TRPM2 | c.1988C>T p.S663F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV55971396; called by muse, mutect2, varscan2
- TRPM3 | c.2035G>A p.A679T (on ENST00000357533 / NM_001366142.2; = p.A522T on NM_020952.6) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV62588356; called by muse, mutect2, varscan2
- TRPM4 | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 121/271 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as rs767457903, COSV53264400; called by muse, mutect2, varscan2
- TULP4 | c.4426G>A p.E1476K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1474225838, COSV100893277, COSV65572881; called by muse, mutect2, varscan2
- UBR5 | c.6671A>T p.K2224I | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV55290656; called by muse, mutect2, varscan2
- UGT8 | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60418643; called by muse, mutect2, varscan2
- UNC5C | c.1523C>G p.S508W | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV71660577; called by muse, mutect2, varscan2
- UNC5CL | c.1002C>G p.I334M | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV55110437; called by muse, mutect2, varscan2
- UTS2B | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 88/164 reads (54%) | catalogued as COSV100484250, COSV100484407; called by muse, mutect2, varscan2
- VCL | c.2968G>T p.A990S (on ENST00000211998 / NM_014000.3; = p.A922S on NM_003373.4) | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1309093890, COSV53010814; called by muse, mutect2, varscan2
- VN1R1 | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.49); catalogued as COSV58091262; called by muse, mutect2, varscan2
- VPS18 | c.2624A>G p.H875R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55030821; called by muse, mutect2, varscan2
- VPS45 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV64888158; called by muse, mutect2, varscan2
- WASF3 | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV58969876; called by muse, mutect2
- WASL | c.117G>T p.V39= | Splice Region (SNP) | VAF 11/35 reads (31%) | catalogued as COSV56134268; called by muse, mutect2, varscan2
- WDFY3 | c.2797C>T p.Q933* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV55693413, COSV99884011; called by muse, mutect2, varscan2
- WDR90 | c.4985A>G p.Y1662C | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53471283; called by muse, mutect2, varscan2
- YARS2 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.08); catalogued as rs1229312979, COSV61402067; called by muse, mutect2, varscan2
- YIPF3 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 3/43 reads (7%) | catalogued as rs1194472060, COSV100396968; called by muse, mutect2
- ZKSCAN8 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV100362904, COSV57638928; called by muse, mutect2, varscan2
- ZNF142 | c.1741A>G p.T581A (on ENST00000411696 / NM_001379660.1; = p.T381A on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV68744159; called by muse, mutect2, varscan2
- ZNF184 | c.889C>G p.Q297E | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV53004545; called by muse, mutect2, varscan2
- ZNF215 | c.801G>A p.W267* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as rs1304923519, COSV99549706; called by muse, mutect2, varscan2
- ZNF300 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV51037346; called by muse, mutect2, varscan2
- ZNF35 | c.695G>C p.S232T | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as COSV56076857; called by muse, mutect2, varscan2
- ZNF431 | c.1154C>G p.S385* | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100218832; called by muse, mutect2, varscan2
- ZNF431 | c.1532C>G p.S511C | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV60673668; called by muse, mutect2, varscan2
- ZNF510 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV56297780; called by muse, mutect2, varscan2
- ZNF516 | c.1709G>A p.S570N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as COSV71587172; called by muse, mutect2, varscan2
- ZNF521 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV64128253; called by muse, mutect2, varscan2
- ZNF547 | c.152-1G>A p.X51_splice | Splice Site (SNP) | VAF 40/68 reads (59%) | catalogued as COSV56580887; called by muse, mutect2, varscan2
- ZNF574 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 61/106 reads (58%) | catalogued as rs1261822794, COSV99726220; called by muse, mutect2, varscan2
- ZNF578 | c.1151C>G p.S384* | Nonsense Mutation (SNP) | VAF 53/150 reads (35%) | catalogued as COSV101405064, COSV69737487; called by muse, mutect2, varscan2
- ZNF638 | c.5464G>C p.E1822Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.261); catalogued as rs1170610243, COSV52489594; called by muse, mutect2, varscan2
- ZNF665 | c.147G>T p.M49I (on ENST00000600412; = p.M114I on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV67215751; called by muse, mutect2
- ZNF7 | c.1802G>C p.R601T | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV100296185, COSV57384111; called by muse, mutect2
- ZNF710 | c.1274_1277del p.H425Rfs*63 | Frame Shift Del (DEL) | VAF 26/54 reads (48%) | catalogued as COSV51563732; called by mutect2, pindel, varscan2
- ZP4 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 36/104 reads (35%) | catalogued as COSV100850703, COSV63911226; called by muse, mutect2, varscan2
- DUSP14 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- KCNK10 | c.1029del p.W343* | Frame Shift Del (DEL) | VAF 8/11 reads (73%) | called by mutect2, varscan2
- KIR2DL4 | c.1207C>G p.Q403E (on ENST00000396284; = p.Q329E on NM_001080770.2) | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.221); called by muse, mutect2
- LILRB3 | c.392G>T p.S131I | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MIER3 | c.1145del p.P382Lfs*5 (on ENST00000381199 / NM_001297599.2; = p.P381Lfs*5 on NM_152622.4) | Frame Shift Del (DEL) | VAF 15/115 reads (13%) | called by mutect2, pindel, varscan2
- MROH1 | c.3406G>C p.G1136R | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OR2T35 | c.754T>A p.Y252N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TCF12 | c.1028dup p.L343Ffs*8 | Frame Shift Ins (INS) | VAF 10/79 reads (13%) | called by mutect2, pindel, varscan2
- UBE2O | c.3820_3830del p.T1274Gfs*79 | Frame Shift Del (DEL) | VAF 46/174 reads (26%) | called by mutect2, pindel, varscan2
- USP36 | c.922_924del p.K308del | In Frame Del (DEL) | VAF 25/74 reads (34%) | called by pindel, varscan2
- ZFP36L1 | c.484_489del p.H162_T163del | In Frame Del (DEL) | VAF 39/67 reads (58%) | called by mutect2, pindel, varscan2
- AAK1 | c.2628T>A p.T876= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV68644498; called by muse, mutect2, varscan2
- ADCY3 | c.330G>C p.V110= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV53168768; called by muse, mutect2, varscan2
- AL645922.1 | c.2997C>A p.A999= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as COSV54961061; called by muse, mutect2, varscan2
- APOB | c.3603T>A p.P1201= | Silent (SNP) | VAF 55/120 reads (46%) | catalogued as COSV51939982; called by muse, mutect2, varscan2
- ARIH2 | c.507C>T p.C169= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV62705141; called by muse, mutect2, varscan2
- ATP8B1 | c.1188C>G p.L396= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV99377112, COSV99377413; called by muse, mutect2
- BMPR2 | c.1134C>G p.G378= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV65810465; called by muse, mutect2, varscan2
- CACNG2 | c.405C>T p.I135= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV55636308; called by muse, mutect2, varscan2
- CALD1 | c.1194C>A p.A398= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV62649017; called by muse, mutect2
- CBX2 | c.1113T>G p.L371= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV53969367; called by muse, mutect2, varscan2
- CCT3 | c.1209G>A p.L403= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV55289587; called by muse, mutect2, varscan2
- CENPJ | c.3966G>A p.R1322= | Silent (SNP) | VAF 34/200 reads (17%) | catalogued as COSV55042655; called by muse, mutect2, varscan2
- CHRD | c.729G>A p.R243= | Silent (SNP) | VAF 112/227 reads (49%) | catalogued as COSV52609293; called by muse, mutect2, varscan2
- CHTOP | c.156C>T p.N52= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as rs1191615910, COSV64155266; called by muse, mutect2
- CILP | c.360C>T p.L120= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV56025216; called by muse, mutect2, varscan2
- CMYA5 | c.10965G>A p.L3655= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV71406672; called by muse, mutect2
- COL11A1 | c.1137C>T p.G379= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs745798103, COSV100615459, COSV62173679; called by muse, mutect2, varscan2
- COL1A2 | c.1245C>T p.G415= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs752359132, COSV51958095, COSV51960154; called by muse, mutect2, varscan2
- CRACDL | c.189C>G p.V63= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV101194166, COSV67408670; called by muse, mutect2
- CRELD1 | c.1218A>T p.S406= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV55977568; called by mutect2, varscan2
- DHRS3 | c.423C>G p.L141= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100879622, COSV66108369; called by muse, mutect2, varscan2
- DNAH1 | c.12249C>G p.L4083= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV56235746; called by muse, varscan2
- DNAH17 | c.10692C>T p.A3564= | Silent (SNP) | VAF 50/121 reads (41%) | catalogued as rs546961324, COSV67756835; called by muse, mutect2, varscan2
- DPYSL4 | c.246C>A p.G82= | Silent (SNP) | VAF 48/65 reads (74%) | catalogued as rs1246602109, COSV58308063; called by muse, mutect2, varscan2
- E4F1 | c.379C>T p.L127= | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as COSV57039601; called by muse, mutect2, varscan2
- ECT2 | c.1794G>A p.Q598= (on ENST00000392692 / NM_001349098.2; = p.Q567= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as COSV51690163; called by muse, mutect2, varscan2
- EHD3 | c.1066C>T p.L356= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV59031412; called by muse, mutect2, varscan2
- ELAVL1 | c.357G>A p.Q119= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV60967075, COSV60967524; called by muse, mutect2, varscan2
- ERRFI1 | c.420C>T p.F140= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV66310786; called by muse, mutect2
- FAM160A2 | c.1164C>T p.L388= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs200972055; called by muse, mutect2, varscan2
- FBN1 | c.2997A>G p.R999= | Silent (SNP) | VAF 51/107 reads (48%) | catalogued as COSV57320209; called by muse, mutect2, varscan2
- FLNA | c.885C>A p.G295= | Silent (SNP) | VAF 59/72 reads (82%) | catalogued as COSV61045546; called by muse, mutect2, varscan2
- FOCAD | c.1692C>T p.F564= | Silent (SNP) | VAF 99/188 reads (53%) | catalogued as rs765615480, COSV58101471; called by muse, mutect2, varscan2
- GABBR1 | c.1224C>T p.I408= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV63543057; called by muse, mutect2, varscan2
- GANAB | c.1377G>A p.K459= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as rs1456381147, COSV100648081; called by muse, mutect2
- GANAB | c.948C>T p.L316= | Silent (SNP) | VAF 28/462 reads (6%) | catalogued as COSV60465687; called by muse, mutect2
- GM2A | c.6G>A p.Q2= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV64095615; called by muse, mutect2, varscan2
- GOLGA4 | c.1020G>A p.E340= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs1351822536, COSV62711451; called by muse, mutect2, varscan2
- HHIP | c.223C>A p.R75= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV56840591, COSV56841602; called by mutect2, varscan2
- HIVEP3 | c.4029C>G p.V1343= | Silent (SNP) | VAF 43/75 reads (57%) | catalogued as COSV56017258; called by muse, mutect2, varscan2
- HOXD13 | c.609G>T p.V203= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as rs1164532665, COSV66832684; called by muse, mutect2, varscan2
- HTR1A | c.672C>T p.F224= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as COSV60501354; called by muse, mutect2, varscan2
- IGKV1D-16 | c.300G>C p.L100= | Silent (SNP) | VAF 60/197 reads (30%) | called by muse, mutect2, varscan2
- KDM1A | c.2367C>T p.A789= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs1439496958, COSV56502404; called by muse, mutect2, varscan2
- KLHL35 | c.915C>T p.I305= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as rs1170872968, COSV100888781, COSV100888795; called by muse, mutect2
- LRP2 | c.12747C>T p.F4249= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as COSV55558532; called by muse, mutect2, varscan2
- MEDAG | c.24G>A p.P8= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs954990902, COSV66850424; called by muse, mutect2, varscan2
- MGAT5B | c.1692C>G p.L564= (on ENST00000569840 / NM_001199172.2; = p.L562= on NM_144677.3) | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV56926485, COSV56930962; called by muse, mutect2, varscan2
- MS4A14 | c.1476C>A p.T492= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as COSV55735637; called by muse, mutect2, varscan2
- MUC16 | c.38892G>A p.R12964= | Silent (SNP) | VAF 28/219 reads (13%) | catalogued as rs1163025932, COSV67474071; called by muse, mutect2, varscan2
- NAA25 | c.1002A>G p.L334= | Silent (SNP) | VAF 61/141 reads (43%) | catalogued as COSV55705228, COSV99927625; called by muse, mutect2, varscan2
- NADK | c.783G>A p.E261= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs1241832416, COSV58273506; called by muse, mutect2, varscan2
- NAPRT | c.222C>T p.D74= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1239604749, COSV99435011; called by muse, mutect2, varscan2
- NCOA5 | c.252G>C p.V84= | Silent (SNP) | VAF 22/185 reads (12%) | catalogued as COSV51645188; called by muse, mutect2, varscan2
- NFATC2 | c.954C>T p.I318= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs1056395742, COSV101044241, COSV65361200; called by muse, mutect2
- NFKBIB | c.783G>C p.L261= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as COSV58003855; called by muse, mutect2, varscan2
- NOC2L | c.1524G>C p.L508= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV58988291; called by muse, mutect2, varscan2
- OR10K1 | c.711C>A p.T237= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV56872515; called by muse, mutect2, varscan2
- OR5H1 | c.768C>G p.L256= | Silent (SNP) | VAF 72/160 reads (45%) | catalogued as COSV100641804, COSV63402616; called by muse, mutect2, varscan2
- OR5L2 | c.189C>T p.L63= | Silent (SNP) | VAF 35/211 reads (17%) | catalogued as rs1437390124, COSV65723825, COSV65724364; called by muse, mutect2, varscan2
- OR7G3 | c.639G>A p.G213= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV59640495; called by muse, mutect2, varscan2
- OR8K3 | c.639A>T p.I213= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV57131913; called by muse, mutect2, varscan2
- PCDH15 | c.5008C>T p.L1670= (on ENST00000644397 / NM_001354429.2; = p.L1612= on NM_001142771.2) | Silent (SNP) | VAF 28/154 reads (18%) | catalogued as rs189102789, COSV64703056; called by muse, mutect2, varscan2
- PCDHA4 | c.1920G>A p.T640= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV63539371; called by muse, mutect2, varscan2
- PCDHB12 | c.846C>A p.S282= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV53397118, COSV53397743; called by muse, mutect2, varscan2
- PDCL2 | c.102T>A p.V34= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV55260992; called by muse, mutect2, varscan2
- PDE4A | c.1521G>C p.L507= (on ENST00000380702 / NM_001111307.2; = p.L268= on NM_006202.3) | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV53357668, COSV53360478; called by muse, mutect2, varscan2
- PDE4B | c.2079G>A p.E693= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV58482035; called by muse, mutect2
- PIGO | c.1479G>A p.G493= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV53054009; called by muse, mutect2, varscan2
- PKHD1L1 | c.1095G>A p.T365= | Silent (SNP) | VAF 85/342 reads (25%) | catalogued as rs755557689, COSV65745580; called by muse, mutect2, varscan2
- POLR3A | c.1608A>G p.E536= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV64931264; called by muse, mutect2, varscan2
- PPIG | c.435C>A p.I145= | Silent (SNP) | VAF 82/164 reads (50%) | catalogued as rs1433579003, COSV53643844; called by muse, mutect2, varscan2
- PRG4 | c.1272C>T p.T424= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs532352521, COSV63355787; called by muse, varscan2
- PRPSAP2 | c.879C>A p.I293= | Silent (SNP) | VAF 11/150 reads (7%) | catalogued as rs1466073298, COSV52066252; called by muse, mutect2
- PRR16 | c.339C>A p.I113= (on ENST00000407149 / NM_001300783.2; = p.I90= on NM_016644.2) | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV65400916, COSV65407205; called by muse, mutect2, varscan2
- RBPJL | c.588G>T p.S196= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV59214112; called by muse, mutect2, varscan2
- RIOK1 | c.975C>T p.L325= | Silent (SNP) | VAF 37/233 reads (16%) | catalogued as rs1251446867, COSV53572299; called by muse, mutect2, varscan2
- RP9 | c.609G>A p.K203= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as rs761033507, COSV99777987; called by mutect2, varscan2
- RYR2 | c.12781C>T p.L4261= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV63691925; called by muse, mutect2, varscan2
- SAMD9 | c.3378C>T p.V1126= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as COSV66076129; called by muse, mutect2, varscan2
- SELE | c.1698C>G p.L566= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs761647024, COSV60976327, COSV60977042; called by muse, mutect2, varscan2
- SEMA3D | c.1758C>T p.D586= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as rs1032514707, COSV52396334; called by muse, mutect2, varscan2
- SH2D2A | c.972G>A p.K324= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as COSV63884955; called by muse, mutect2, varscan2
- SH3TC1 | c.3963G>A p.L1321= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV55285679; called by muse, mutect2, varscan2
- SI | c.1104G>C p.V368= | Silent (SNP) | VAF 63/438 reads (14%) | catalogued as COSV100015430, COSV52284041; called by muse, mutect2, varscan2
- SKA1 | c.570C>T p.T190= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV53279163; called by muse, mutect2, varscan2
- SLC14A2 | c.576G>A p.L192= | Silent (SNP) | VAF 9/136 reads (7%) | catalogued as COSV54910295; called by muse, mutect2
- SLC24A3 | c.1890C>T p.F630= | Silent (SNP) | VAF 16/350 reads (5%) | catalogued as COSV60122482; called by muse, mutect2
- SOAT2 | c.1546C>A p.R516= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV56859418, COSV56859879; called by muse, mutect2
- STXBP4 | c.654G>A p.E218= | Silent (SNP) | VAF 73/303 reads (24%) | catalogued as rs781122310, COSV54842161, COSV54842878; called by muse, mutect2, varscan2
- TANC1 | c.2715C>G p.L905= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV55089920; called by muse, mutect2, varscan2
- TET1 | c.1560G>A p.E520= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV65385751; called by muse, mutect2, varscan2
- TRAK2 | c.2193C>T p.S731= | Silent (SNP) | VAF 66/93 reads (71%) | catalogued as rs191512628; called by muse, mutect2, varscan2
- TSPYL6 | c.912C>T p.F304= | Silent (SNP) | VAF 21/171 reads (12%) | catalogued as rs372726545; called by muse, mutect2, varscan2
- TTC29 | c.759C>A p.A253= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV57277503; called by muse, mutect2
- UNC5C | c.1411C>T p.L471= | Silent (SNP) | VAF 90/272 reads (33%) | catalogued as COSV71660578; called by muse, mutect2, varscan2
- USP2 | c.429A>G p.Q143= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs370779529; called by muse, mutect2, varscan2
- VCP | c.993C>T p.L331= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV62721004; called by muse, mutect2, varscan2
- VNN2 | c.1098C>T p.C366= | Silent (SNP) | VAF 56/126 reads (44%) | catalogued as rs977332042, COSV58472932; called by muse, mutect2, varscan2
- WDR11 | c.3051G>T p.L1017= | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as COSV54789570; called by muse, mutect2, varscan2
- XIRP2 | c.243G>T p.V81= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV54709265; called by muse, mutect2, varscan2
- ZCCHC3 | c.528C>T p.G176= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs1347513602, COSV66643401; called by muse, mutect2, varscan2
- ZMYND8 | c.2727C>G p.V909= (on ENST00000311275 / NM_001363741.2; = p.V883= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/159 reads (4%) | catalogued as COSV53689937; called by muse, mutect2
- ZNF528 | c.205C>T p.L69= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV64619828; called by muse, mutect2
- ZNF831 | c.2778T>A p.P926= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV64041611; called by muse, mutect2, varscan2
- ZSWIM3 | c.816C>T p.F272= | Silent (SNP) | VAF 11/116 reads (9%) | catalogued as COSV54848521; called by muse, mutect2, varscan2
- ACP1 | c.231+88C>T | Intron (SNP) | VAF 6/46 reads (13%) | catalogued as rs1423760695, COSV55243826; called by muse, mutect2
- AFDN | chr6:167826117 G>A | 5'Flank (SNP) | VAF 15/79 reads (19%) | catalogued as rs768311771; called by muse, mutect2, varscan2
- DCHS2 | n.345G>T | RNA (SNP) | VAF 18/68 reads (26%) | catalogued as COSV59729518; called by muse, mutect2, varscan2
- DCHS2 | n.344T>A | RNA (SNP) | VAF 17/65 reads (26%) | catalogued as COSV59729535; called by muse, mutect2, varscan2
- HIPK1 | c.3144+25C>A | Intron (SNP) | VAF 8/88 reads (9%) | catalogued as COSV61247220, COSV61248656; called by muse, mutect2
- KIF1B | c.2115+6456G>A | Intron (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99823586; called by muse, mutect2
- LINC00173 | n.921G>A | RNA (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- PHACTR1 | c.251-119655G>A | Intron (SNP) | VAF 13/82 reads (16%) | catalogued as rs754036512, COSV60666512; called by muse, mutect2, varscan2
- PPP1CB | chr2:28751810 C>A | 5'Flank (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99941876; called by muse, mutect2, varscan2
- PREX2 | c.2716-2902C>T | Intron (SNP) | VAF 52/230 reads (23%) | catalogued as COSV99907968; called by muse, mutect2, varscan2
- SLC25A25 | c.262-9069G>A | Intron (SNP) | VAF 15/87 reads (17%) | catalogued as COSV66088515; called by muse, mutect2, varscan2
- SLC38A10 | c.2065+225C>T | Intron (SNP) | VAF 23/60 reads (38%) | catalogued as rs374319971; called by muse, mutect2, varscan2
- SNORD115-9 | n.14G>A | RNA (SNP) | VAF 21/253 reads (8%) | called by muse, mutect2
- UROC1 | c.903-540G>A | Intron (SNP) | VAF 36/65 reads (55%) | catalogued as rs1425552953, COSV52034856; called by muse, mutect2, varscan2
